Somatic mutation profile of tumor specimen 0DEV4S from CCDI case PBBPWD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Overlapping lesion of respiratory system and intrathoracic organs; Age at diagnosis: 15.0 years (5,463 days).
Specimen 0DEV4S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0923d088-deed-4a77-a446-be6dadd076fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEV2B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46d619d2-5824-4416-b3e4-39528d0ad277

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Silent 2, Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSR3 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs888194280; called by mutect2, varscan2
- ZAN | c.8239C>T p.R2747* | Nonsense Mutation (SNP) | VAF 236/431 reads (55%) | catalogued as rs370421043, COSV61809168; called by muse, mutect2, varscan2
- JAKMIP3 | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CCDC85A | c.912G>A p.T304= | Silent (SNP) | VAF 139/168 reads (83%) | catalogued as rs1001155155, COSV68155624; called by muse, mutect2, varscan2
- PCDH19 | c.438G>C p.T146= | Silent (SNP) | VAF 117/350 reads (33%) | catalogued as rs776584913, COSV99719712; called by muse, mutect2, varscan2
- CFAP74 | c.3528-29G>A | Intron (SNP) | VAF 31/85 reads (36%) | catalogued as rs1211312453; called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, varscan2
